Somatic mutation profile of tumor specimen TCGA-D7-A6F0-01A (aliquot TCGA-D7-A6F0-01A-11D-A31L-08) from TCGA case TCGA-D7-A6F0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 79.2 years (28,923 days).
Specimen TCGA-D7-A6F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f29af9e-e798-4b0e-87c2-f42b4a5bb3f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6F0-10A (Blood Derived Normal), aliquot TCGA-D7-A6F0-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ea63d83-f9a6-4635-a8e4-e8cf83482317

The open-access MAF lists 136 somatic variants for this specimen: 94 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 39, Nonsense Mutation 6, Intron 2, Frame Shift Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 36/44 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99685348; called by muse, mutect2, varscan2
- ADGRD1 | c.1308C>A p.N436K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99894892; called by muse, mutect2
- AMPH | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as COSV100341661; called by muse, mutect2, varscan2
- AMY1C | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 32/951 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as COSV100915190, COSV100915201; called by muse, mutect2
- ANKRD50 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV101538922, COSV72384978; called by muse, mutect2, varscan2
- ASNS | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs769236847, COSV99446150; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ATG4A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs768783011, COSV100619669; called by muse, mutect2, varscan2
- ATP8B1 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as COSV99377135; called by muse, mutect2, varscan2
- AXDND1 | c.1066A>G p.K356E | Missense Mutation (SNP) | VAF 64/498 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.253); catalogued as COSV100858315; called by muse, mutect2, varscan2
- BCOR | c.4082G>C p.R1361T (on ENST00000378444 / NM_001123385.2; = p.R1327T on NM_017745.6) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100653133; called by muse, mutect2, varscan2
- BRWD3 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100956639, COSV64745075; called by muse, mutect2
- C4BPA | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV100891186; called by muse, mutect2, varscan2
- CATSPERB | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV99831120; called by muse, mutect2, varscan2
- CHD5 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52408505; called by muse, mutect2, varscan2
- CLEC3A | c.161A>T p.K54M (on ENST00000651443; = p.K45M on NM_005752.6) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100222170; called by muse, mutect2, varscan2
- CNTN5 | c.2285C>A p.P762Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99675448; called by muse, mutect2, varscan2
- COL21A1 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs371319505; called by muse, varscan2
- CSMD2 | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150609588; called by muse, mutect2, varscan2
- CSN2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100778765; called by muse, mutect2, varscan2
- CUL4A | c.1244C>T p.S415L (on ENST00000375440 / NM_001008895.4; = p.S315L on NM_003589.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV100417156; called by muse, mutect2, varscan2
- DMBT1 | c.2411G>C p.G804A | Missense Mutation (SNP) | VAF 153/213 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100352650, COSV100352669; called by muse, mutect2, varscan2
- DNAH11 | c.9441A>C p.K3147N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100178599; called by muse, mutect2, varscan2
- DYNC1H1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.638); catalogued as COSV100794736; called by muse, mutect2, varscan2
- EBF2 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV101282140; called by muse, mutect2, varscan2
- ELOA2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 101/141 reads (72%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs762910980, COSV99796327; called by muse, mutect2, varscan2
- FAM160A2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 82/104 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs369770659, COSV99791935; called by muse, mutect2, varscan2
- FAT3 | c.12235G>C p.G4079R | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53103123, COSV99964624; called by muse, mutect2, varscan2
- FCER1A | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV63667515; called by muse, mutect2, varscan2
- FLG | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.438); catalogued as rs1467251068, COSV100911429; called by muse, mutect2, varscan2
- GLI3 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023078, COSV101229814; called by muse, mutect2, varscan2
- IRAK1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs1557130371, COSV57653308; called by muse, mutect2
- ITPRID2 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100238129, COSV57472300; called by muse, mutect2, varscan2
- KHDRBS2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV99832770; called by muse, mutect2, varscan2
- KLHL14 | c.992C>G p.P331R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as COSV100808862; called by muse, mutect2, varscan2
- KLRC2 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101122671, COSV67899690; called by muse, varscan2
- KMT5B | c.837T>G p.C279W | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069910; called by muse, mutect2, varscan2
- LMNTD2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs759285014, COSV54238281; called by muse, mutect2
- LRP2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99787655, COSV99787782; called by muse, mutect2, varscan2
- LRRIQ1 | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373547571; called by muse, mutect2, varscan2
- MAGEB2 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.125); catalogued as COSV100975634; called by muse, mutect2, varscan2
- MAGEL2 | c.2888C>A p.A963E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100045867; called by muse, mutect2, varscan2
- MAST3 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99444888; called by muse, mutect2
- MEOX2 | c.558A>T p.K186N | Missense Mutation (SNP) | VAF 59/83 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100012102; called by muse, mutect2, varscan2
- MGRN1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV99274005; called by muse, mutect2, varscan2
- MIA3 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233058257, COSV100719403; called by muse, mutect2, varscan2
- MKI67 | c.6072G>T p.K2024N | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as rs750960623, COSV100896409; called by muse, mutect2, varscan2
- MYH7B | c.5113C>T p.R1705W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1247217032, COSV99328198; called by muse, mutect2
- MYO9A | c.7571G>A p.R2524H | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs199960921, COSV100613152; called by muse, mutect2, varscan2
- NDST3 | c.685G>C p.A229P | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99630179; called by muse, mutect2, varscan2
- NEK10 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as rs781114388, COSV99835034; called by muse, mutect2, varscan2
- NEUROG2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs372471017; called by muse, mutect2, varscan2
- NRXN1 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 137/409 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as rs781319797, COSV58452486; called by muse, mutect2, varscan2
- NUP43 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100462031; called by muse, mutect2, varscan2
- OR11L1 | c.108C>A p.C36* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100869413; called by muse, mutect2, varscan2
- PEG3 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs754147449, COSV55626776, COSV55635378; called by muse, mutect2, varscan2
- PGR | c.2733A>C p.E911D | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs865856373, COSV54798625, COSV99678444; called by muse, mutect2, varscan2
- PNPLA5 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99336581; called by muse, mutect2
- POMT1 | c.855G>C p.L285F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs201073763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIP5K2 | c.3424C>A p.Q1142K (on ENST00000358359 / NM_001276277.3; = p.Q1121K on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1289244796, COSV100383669; called by muse, mutect2, varscan2
- PPP1R16A | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373164819; called by muse, mutect2, varscan2
- PREP | c.1027C>A p.H343N (on ENST00000369110; = p.H409N on NM_002726.5) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV100963844; called by muse, mutect2
- PRKAR1B | c.29A>C p.E10A | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.16); catalogued as COSV100816613; called by muse, mutect2, varscan2
- PTPRT | c.2922G>A p.M974I | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100626541, COSV61975141; called by muse, mutect2, varscan2
- PWWP3B | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100531123; called by muse, mutect2, varscan2
- RBBP6 | c.4234G>T p.E1412* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100154500; called by muse, mutect2, varscan2
- RBBP7 | c.752T>G p.L251R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100417883; called by muse, mutect2, varscan2
- RSU1 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100590336; called by muse, mutect2, varscan2
- SBNO2 | c.2161A>C p.K721Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as COSV100684380; called by muse, mutect2, varscan2
- SFMBT2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760397823, COSV62808284; called by muse, mutect2, varscan2
- SHF | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs200925244, COSV99334377; called by muse, mutect2, varscan2
- SI | c.3808A>C p.T1270P | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100015005; called by muse, mutect2
- SIPA1L2 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99477878; called by muse, mutect2
- SLC39A8 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765685; called by muse, mutect2, varscan2
- SLIT2 | c.4390A>C p.K1464Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV56583472; called by muse, mutect2, varscan2
- STPG3 | c.889C>T p.P297S (on ENST00000388931 / NM_001256699.1; = p.I291= on NM_001004353.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100546857; called by muse, mutect2, varscan2
- TCTE1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs374735103, COSV65255452; called by muse, mutect2, varscan2
- TDRD1 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1165387144, COSV99313802, COSV99315111; called by muse, mutect2, varscan2
- TENM3 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs753241518, COSV101305019; called by muse, mutect2, varscan2
- TMEM132B | c.2753A>G p.N918S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100169226; called by muse, mutect2, varscan2
- TMEM150C | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.297); catalogued as COSV101497302; called by muse, mutect2, varscan2
- TNN | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV53429664; called by muse, mutect2, varscan2
- TPTE | c.970G>A p.E324K (on ENST00000618007 / NM_199261.4; = p.E306K on NM_199259.4) | Missense Mutation (SNP) | VAF 93/493 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs771577928; called by muse, mutect2, varscan2
- UBASH3B | c.1871T>G p.L624R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99417400; called by muse, mutect2, varscan2
- USH2A | c.7037A>C p.H2346P | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs776390437, COSV100232752; called by muse, mutect2, varscan2
- UTRN | c.7117C>A p.Q2373K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV100839796; called by muse, mutect2, varscan2
- WDR54 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs765087003, COSV99269507; called by muse, mutect2
- YIF1A | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100268376; called by muse, mutect2, varscan2
- ZBTB7A | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100475580; called by muse, mutect2, varscan2
- ZNF266 | c.462A>C p.K154N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100749368; called by muse, mutect2, varscan2
- ZNF800 | c.1100A>G p.K367R | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV99757823; called by muse, mutect2, varscan2
- ZNF804A | c.2115T>G p.N705K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV100167328; called by muse, mutect2, varscan2
- ASCC3 | c.2215del p.A739Qfs*55 | Frame Shift Del (DEL) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- CHTF8 | c.24-5_29delinsCGAGT p.X8_splice | Splice Site (DEL) | VAF 24/153 reads (16%) | called by pindel, varscan2*
- ABCG8 | c.1266G>A p.A422= | Silent (SNP) | VAF 106/300 reads (35%) | catalogued as rs567600982, COSV99699654; called by muse, mutect2, varscan2
- ADAM18 | c.1863A>T p.G621= | Silent (SNP) | VAF 65/103 reads (63%) | catalogued as COSV99695343; called by muse, mutect2, varscan2
- C4orf50 | c.507A>G p.S169= (on ENST00000324058; = p.S1401= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as COSV100135770; called by muse, mutect2, varscan2
- CCDC146 | c.1455C>T p.N485= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99592450; called by muse, mutect2, varscan2
- CLDN9 | c.79C>T p.L27= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100172128; called by muse, mutect2, varscan2
- CSMD3 | c.591G>C p.G197= | Silent (SNP) | VAF 100/153 reads (65%) | catalogued as COSV52152696, COSV99831117; called by muse, mutect2, varscan2
- DCK | c.306C>G p.L102= | Silent (SNP) | VAF 70/113 reads (62%) | catalogued as COSV54377489, COSV54378770; called by muse, mutect2, varscan2
- DGKQ | c.1317G>A p.E439= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as COSV99892549; called by muse, mutect2, varscan2
- ELOC | c.213G>A p.S71= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs776346914, COSV53024257; called by muse, mutect2, varscan2
- FMNL3 | c.2256G>A p.A752= | Silent (SNP) | VAF 83/159 reads (52%) | catalogued as rs751577308, COSV53304802; called by muse, mutect2, varscan2
- FZD2 | c.582G>A p.T194= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100190343; called by muse, mutect2
- GNAO1 | c.774G>A p.K258= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99341018; called by muse, mutect2, varscan2
- GREB1 | c.5823C>G p.L1941= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV52193209; called by muse, mutect2, varscan2
- HCAR2 | c.1020C>T p.G340= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as rs200668464, COSV61025017; called by muse, mutect2, varscan2
- IRX2 | c.1197C>T p.N399= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as rs749189949, COSV57410486; called by muse, mutect2, varscan2
- KLK5 | c.69C>T p.V23= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as rs968237541, COSV60450299; called by muse, mutect2, varscan2
- LANCL1 | c.663G>T p.L221= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- LAYN | c.441C>T p.S147= (on ENST00000375615 / NM_001258390.1; = p.S139= on NM_178834.5) | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs1160811547, COSV100986194; called by muse, mutect2, varscan2
- LRRC43 | c.1788T>G p.S596= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100148671; called by muse, mutect2
- LTB4R | c.261G>C p.L87= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV99350625; called by muse, mutect2, varscan2
- MRPS18B | c.165C>A p.P55= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV99457649; called by muse, mutect2, varscan2
- MYOM2 | c.2220G>A p.S740= | Silent (SNP) | VAF 134/216 reads (62%) | catalogued as rs531014414, COSV100037279; called by muse, mutect2, varscan2
- NCOR2 | c.3981C>T p.I1327= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs956696290, COSV100657155, COSV62296994; called by muse, mutect2, varscan2
- NLRP14 | c.957G>A p.L319= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV100204748; called by muse, mutect2, varscan2
- NYAP1 | c.1785C>T p.T595= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs760408434, COSV55719010; called by muse, mutect2, varscan2
- PELO | c.324C>G p.R108= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99251084; called by muse, mutect2, varscan2
- PLEKHF1 | c.198C>T p.S66= | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as rs146769630; called by muse, mutect2, varscan2
- PTPN11 | c.1011G>A p.T337= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs371951288, COSV100692796; ClinVar: likely benign; called by muse, mutect2, varscan2
- PXDN | c.2235C>T p.D745= | Silent (SNP) | VAF 99/209 reads (47%) | catalogued as rs553601622, COSV99413084; called by muse, mutect2, varscan2
- RIMS1 | c.129G>A p.Q43= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99325762; called by muse, mutect2, varscan2
- RTN4RL2 | c.369G>A p.E123= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV100625432; called by muse, mutect2
- RUBCNL | c.1479G>T p.L493= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100528978; called by muse, mutect2
- SIPA1L3 | c.1362C>T p.S454= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV55917658; called by muse, mutect2, varscan2
- SLC44A3 | c.1335C>A p.I445= (on ENST00000271227 / NM_001114106.3; = p.I397= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/203 reads (60%) | catalogued as COSV99598029; called by muse, mutect2, varscan2
- SPRY2 | c.456G>A p.V152= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs1387298568, COSV101001677; called by muse, mutect2, varscan2
- STARD3 | c.525C>A p.P175= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV100302775; called by muse, mutect2
- TBC1D20 | c.750G>A p.P250= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs372373111; called by muse, mutect2, varscan2
- TCFL5 | c.1002G>A p.A334= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs193288319; called by muse, mutect2, varscan2
- XIAP | c.750C>T p.F250= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs1335120157, COSV100848843; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481-1965del | Intron (DEL) | VAF 24/145 reads (17%) | catalogued as COSV66402045; called by mutect2, pindel, varscan2
- KRT18P23 | chr22:44570564 G>A | 3'Flank (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- PDE4B | c.281+74203A>G | Intron (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100303093; called by muse, mutect2, varscan2
